Gene-level copy-number profile of tumor specimen TCGA-PC-A5DN-01A from TCGA case TCGA-PC-A5DN, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 77.8 years (28,421 days).
Specimen TCGA-PC-A5DN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.f09fb97e-e893-482a-bca1-5f372353bfd5.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-PC-A5DN-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a1120487-e01b-4116-981e-5ad63a9ceb66

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 28; copy number 1: 401; copy number 2: 55,645; copy number 3: 1,065; copy number 4: 2,166; copy number 5: 15; copy number 7: 26; copy number 10: 4; copy number 11: 1; copy number 12: 8; copy number 14: 24; copy number 15: 11; copy number 16: 5; copy number 17: 14; copy number 18: 10; copy number 19: 11; copy number 20: 23; copy number 21: 12; copy number 22: 17; copy number 23: 3; copy number 24: 7; copy number 25: 34; copy number 26: 9; copy number 27: 14; copy number 28: 5; copy number 29: 5; copy number 30: 1; copy number 32: 15; copy number 33: 15; copy number 36: 24; copy number 37: 22; copy number 39: 89; copy number 44: 23; copy number 45: 6; copy number 47: 13; copy number 50: 9; copy number 62: 5; copy number 64: 28.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-PC-A5DN-01A-12D-A27O-01): tumor purity 0.61, ploidy 2.06, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 28 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:232,397,965–232,918,018, 8 genes (within-gene range 0–3): SIPA1L2, RNU6-1211P, LINC01745, LINC01744, MAP10, RNU1-74P, AL122003.2, AL122003.1.
- chr20:59,577,509–59,847,711, 1 gene (within-gene range 0–2): PHACTR3.
- chr20:59,852,667–61,083,750, 16 genes: RNU7-141P, SYCP2, FAM217B, PPP1R3D, CDH26, C20orf197, AL132822.1, MIR646HG, MIR646, MTCO2P1, MIR4533, MIR548AG2, AL117372.1, AL139348.1, AL121910.1, LINC01718.
- chr20:61,267,525–61,437,630, 3 genes: AL365229.1, BX640515.1, AL160412.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 508 genes in 61 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:167,607–206,392, 4 genes, copy number 21–32: AL035696.2, AL035696.3, AL035696.4, AL035696.1.
- chr6:10,574,749–11,155,150, 21 genes, copy number 14: AL139039.2, GCNT2P1, AL358777.3, C6orf52, Y_RNA, PAK1IP1, TMEM14C, AL024498.1, TMEM14B, AL024498.2, RNA5SP203, MAK, GCM2, AL357497.1, SYCP2L, ELOVL2, AL121955.1, ELOVL2-AS1, SMIM13, ERVFRD-1, AL136139.1.
- chr6:20,401,879–20,500,276, 5 genes, copy number 32: E2F3, RN7SL128P, E2F3-IT1, RNU6-141P, Y_RNA.
- chr6:34,236,873–34,426,071, 7 genes, copy number 17 (within-gene range 2–17): HMGA1, MIR6835, SMIM29, AL354740.1, RPL35P2, NUDT3, RPS10-NUDT3.
- chr6:35,733,867–35,766,927, 3 genes, copy number 21: AL157823.2, ARMC12, AL157823.1.
- chr6:42,101,119–42,194,956, 5 genes, copy number 29: C6orf132, AL096814.1, AL096814.2, GUCA1A, GUCA1B.
- chr6:44,113,451–44,184,401, 3 genes, copy number 23: MRPL14, TMEM63B, CAPN11.
- chr7:48,171,458–50,121,329, 14 genes, copy number 5 (within-gene range 2–5): ABCA13, AC091770.1, LINC02838, AC004899.1, AC004899.2, GDI2P1, CDC14C, AC091730.1, DDX43P2, AC092448.1, AC093775.1, VWC2, ZPBP, GNL2P1.
- chr12:280,057–442,642, 2 genes, copy number 15 (within-gene range 3–15): KDM5A, CCDC77.
- chr12:12,049,844–12,267,044, 5 genes, copy number 21 (within-gene range 2–21): BCL2L14, PTMAP9, MIR1244-4, LRP6, AC007537.1.
- chr12:12,813,316–12,917,937, 6 genes, copy number 22: DDX47, AC007215.1, AC007688.2, RPL13AP20, GPRC5A, MIR614.
- chr12:14,250,232–14,365,503, 3 genes, copy number 19: RNU6-491P, GNAI2P1, RPL30P11.
- chr12:22,104,491–22,195,629, 3 genes, copy number 33: AC007671.1, SULT6B2P, RNU1-149P.
- chr12:23,108,458–23,251,499, 3 genes, copy number 19: AC087258.1, AC087235.2, AC087235.1.
- chr12:25,092,715–25,195,162, 4 genes, copy number 32 (within-gene range 2–32): CENPUP2, AC023510.1, AC023510.2, CFAP94.
- chr12:26,125,155–26,167,741, 2 genes, copy number 18: AC022509.3, AC022509.5.
- chr12:50,743,568–51,173,135, 21 genes, copy number 20 (within-gene range 2–20): Y_RNA, AC013244.1, ATF1, AC013244.2, RN7SL519P, TMPRSS12, AC013244.3, METTL7A, AC008121.2, Y_RNA, AC008121.1, HIGD1C, AC008121.3, SLC11A2, RNU6-87P, RNU6-1273P, LETMD1, CSRNP2, TFCP2, RPL35AP29, PHBP19.
- chr12:56,663,341–58,813,060, 89 genes, copy number 39 (within-gene range 1–39) (broad region; genes not listed).
- chr12:59,020,169–60,096,071, 13 genes, copy number 47: RPS6P22, AC068305.1, AC046129.1, AC108721.2, AC108721.1, RNU6-279P, RNU6-871P, LINC02448, RNU4-20P, SLC16A7, AC079905.2, AC079905.1, AC080011.1.
- chr12:61,231,159–61,702,771, 3 genes, copy number 45: AC090017.1, DUX4L52, AC090629.1.
- chr12:65,758,020–67,069,162, 23 genes, copy number 44 (within-gene range 2–44): RPSAP52, HMGA2, AC107308.1, HMGA2-AS1, AC090673.1, MIR6074, LINC02425, RPL21P18, RNA5SP362, LLPH, AC078927.1, LLPH-DT, TMBIM4, IRAK3, RBMS1P1, MIR6502, AC078889.1, PDCL3P7, RN7SKP166, HELB, GRIP1, OSBPL9P5, OSBPL9P4.
- chr12:67,443,105–71,118,247, 80 genes, copy number 25–64 (within-gene range 2–64) (broad region; genes not listed).
- chr12:73,648,666–73,679,296, 2 genes, copy number 45: AC087879.1, RNU6-1012P.
- chr12:75,040,077–75,298,508, 3 genes, copy number 10 (within-gene range 2–10): KCNC2, CAPS2-AS1, CCNG2P1.
- chr12:75,926,213–79,935,460, 54 genes, copy number 12–64 (within-gene range 2–75): AC011611.6, RN7SL734P, AC011611.2, AC011611.1, PHLDA1, AC011611.3, AC011611.4, NAP1L1, AC011611.5, AC233290.2, AC233290.1, RNU6-1271P, LNCOG, RN7SKP172, BBS10, OSBPL8, AC107032.2, AC107032.3, RPL7AP9, YWHAQP7, AC107032.1, RPL7P43, AC093014.1, ZDHHC17, CSRP2, AC124784.1, AC025161.1, E2F7, AC079030.1, LINC02464, NAV3, AC073591.1, AC138331.1, AC073571.1, PRXL2AP1, LINC02424, AC128707.1, AC130415.1, AC079362.1, AC068993.1, AC068993.2, SYT1, AC090709.1, AC027288.3, MIR1252, AC027288.2, AC027288.1, NOP56P3, PAWR, AC073569.2, PPP1R12A, AC073569.3, AC073569.1, RNA5SP363.
- chr12:87,944,885–88,142,099, 5 genes, copy number 11–15 (within-gene range 2–17): RPS4XP15, C12orf50, C12orf29, CEP290, RNA5SP364.
- chr12:89,500,093–89,548,005, 5 genes, copy number 19: CENPCP1, POC1B-GALNT4, GALNT4, POC1B-AS1, AC025034.2.
- chr12:93,894,965–93,947,813, 2 genes, copy number 18 (within-gene range 2–18): AC012464.1, AC012464.3.
- chr12:96,194,375–96,400,480, 5 genes, copy number 62 (within-gene range 2–62): ELK3, AC008149.1, AC008149.2, CDK17, RNU4-24P.
- chr12:97,150,081–97,160,538, 2 genes, copy number 21: AC007656.3, AC007656.4.
- chr12:97,430,884–97,598,415, 14 genes, copy number 27 (within-gene range 2–27): RMST, MIR1251, AC007351.2, AC007351.3, AC007351.4, AC007351.1, AC018659.4, AC018659.3, AC018659.1, AC018659.7, AC018659.5, AC018659.8, MIR135A2, AC018659.6.
- chr12:98,453,835–98,606,379, 7 genes, copy number 17: SLC9A7P1, LINC02453, TMPO-AS1, TMPO, PPIAP8, SLC25A3, SNORA53.
- chr12:102,073,103–102,197,833, 3 genes, copy number 14 (within-gene range 2–14): NUP37, PARPBP, PMCH.
- chr12:106,015,897–106,172,437, 5 genes, copy number 24: ST13P3, AC011595.2, NUAK1, AC011595.1, AC010182.1.
- chr12:117,889,454–118,033,130, 3 genes, copy number 28: AC084291.1, RFC5, AC131159.2.
- chr12:119,225,834–119,681,624, 7 genes, copy number 26: AC084880.2, LINC00934, CCDC60, AC002070.1, TMEM233, RN7SKP197, PRKAB1.
- chr12:120,721,507–120,904,358, 5 genes, copy number 16 (within-gene range 2–29): AC069234.3, MIR4700, ACADS, AC069234.1, SPPL3.
- chr12:123,233,436–123,441,852, 11 genes, copy number 22 (within-gene range 2–22): C12orf65, CDK2AP1, AC068768.1, RNA5SP375, SBNO1, Y_RNA, SBNO1-AS1, MIR8072, KMT5A, RILPL2, COPS5P2.
- chr12:124,593,181–124,638,444, 4 genes, copy number 18: AC073592.8, AC073592.2, AC073592.10, AC073592.4.
- chr21:46,052,596–46,665,124, 26 genes, copy number 7: AP001476.3, AP001476.2, PSMA6P3, AP001471.1, COL6A2, FTCD, FTCD-AS1, SPATC1L, AP001468.1, LSS, AP001469.1, MCM3AP-AS1, MCM3AP, AP001469.2, AP001469.3, YBEY, C21orf58, PCNT, AP000471.1, RPL18AP2, DIP2A, DIP2A-IT1, RNU6-396P, S100B, PRMT2, DSTNP1.

Autosomal genes at a single copy (total copy number 1): 401. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
